Surgical pathology report (de-identified scan), TCGA case TCGA-23-1026, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1026-01B (Primary Tumor).

[page 1 of 5]
SURGICAL
PATIENT:
Hospital
Date of B

PATH #.
A/S: F
Rec:
Col:

Location:
Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

=====

DIAGNOSIS:

1,2,3&4. OMENTUM #1 THROUGH #4:

- Omental tissue with multiple foci of benign mesothelial hyperplasia
- Minute intra-omental lymph nodes with benign reactive changes (section D)

5. LEFT TUBE AND OVARY, SALPINGO-OOPHORECTOMY:

- Serous papillary adenocarcinoma, ovary
- High grade
- Tumor replaces most of the ovarian parenchyma extending into fallopian tube and paraovarian tissue
- Involutional changes contiguous ovary
- Paratubal cyst (hydatid of Morgagni)
- Chronic salpingitis

6. RIGHT OVARY AND TUBE, SALPINGO-OOPHORECTOMY:

- Serous papillary adenocarcinoma
- High grade
- Tumor replaces most of the ovarian tissue
- Hemorrhagic corpus luteum cyst minimal changes, adjacent ovary
- Fallopian tube with chronic salpingitis, fibrosis and tubo-ovarian adhesions

7. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- Tumor deposits in bilateral parametria
- Metastatic tumor deposit subserosal, anterior uterine wall
- Benign endocervix with reactive changes including tunnel clusters and nabothian cysts
- Benign remaining myometrium with unremarkable endometrium

8&9. PELVIC TUMOR, RECTOSIGMOID TUMOR:

- Metastatic serous papillary adenocarcinoma, high grade

(continued on next page)□

Page: 2

10. APPENDIX, APPENDECTOMY:

- Mucosal fibrosis with luminal obliteration, benign appendix

11. DIAPHRAGM TUMOR, BIOPSY:

- Metastatic serous papillary adenocarcinoma, high grade

12. GASTROCOLIC LIGAMENT NODULE:

- Benign reactive lymph nodes negative for metastatic tumor

[page 2 of 5]
13. LEFT PELVIC LYMPH NODE:
- Negative for metastatic tumor
- Benign fibroadipose tissue with no lymph node tissue identified
- 14,15&16. LEFT OBTURATOR LYMPH NODE, RIGHT OBTURATOR LYMPH NODE, RIGHT PELVIC LYMPH NODE, BIOPSIES:
- Negative for metastatic carcinoma
- Benign lymph nodes and contiguous fibroadipose tissue
17. RIGHT VAGINAL TUMOR, BIOPSY:
- Metastatic serous papillary adenocarcinoma, high grade
- Tumor replaces most of biopsied tissue

=====

HISTORY: Pelvic mass

MICROSCOPIC:

Sections of the tumor exhibit a high grade neoplasm which is solid and focally papillary. Mitoses are numerous. Cells exhibit high N/C ratio. In some areas there is mucin production seen, however it is mostly extracellular. Rare cells though seem to contain intracellular mucin vacuoles i.e. "serous papillary carcinoma with foci of mucinous carcinoma".

GROSS:

1: OMENTUM 1

Labeled with the patient's name, designated "omentum #1", and received in formalin is a 13.0 x 7.0 x 0.5 cm irregular, firm, yellow-brown portion of fibroadipose tissue. No definite lymph nodes or solid areas grossly identified. Representative sections.

A. 2

2: OMENTUM 2

Labeled with the patient's name, designated "omentum #2", and received in formalin are two irregular, firm, yellow-brown portions of tissue measuring 3.5 x 3.0 x 0.5 cm and 12.0 x 5.0 x 0.5 cm. No definite nodes or solid area are identified grossly. Representative section.

B. 2

3: OMENTUM 3

(continued on next page)□

1

Page: 3

Labeled with the patient's name, designated "omentum #3", and received in formalin is a 10.0 x 8.5 x 0.8 cm irregular, firm, yellow-brown portion of fibroadipose tissue. The specimen is remarkable for a 0.7 x 0.7 x 0.5 cm irregular, firm area. Representative sections are submitted.

C. 2

4: OMENTUM 4

Labeled with the patient's name, designated "omentum #4", and received in formalin is a 11.0 x 7.0 x 0.6 cm irregular, yellow-brown firm portion of fibroadipose tissue. The specimen is remarkable for a 0.3 x 0.3 x 0.2 cm irregular, firm area. Representative sections are submitted.

D. 2

[page 3 of 5]
5: LEFT TUBE AND OVARY FS1

Labeled with the patient's name, designated "left tube and ovary", and received fresh in the Operating Room for the intraoperative frozen section diagnosis and subsequently fixed in formalin is a 6.0 cm long segment of fallopian tube measuring up to 1.0 cm in the external diameter. The external surface of the fallopian tube is mostly tan-gray and smooth. There is a 1.3 x 1.0 x 0.7 cm paratubal cyst identified. Attached to the fallopian tube is a markedly distorted ovarian tissue measuring up to 5.5 x 4.0 x 2.0 cm. The markedly distorted ovarian tissues/tumor is previously incised in the Operating Room for the intraoperative frozen section diagnosis. The cut surface of this mass is partially solid and partially cystic. There are areas of yellow, firm, smooth area and there are focal areas of hemorrhage. No normal ovarian parenchyma is identified. Representative sections are submitted as follows.

E. Frozen section control #1 - 2

F. Portion of fallopian tube with tumor and the paratubal cyst - 1

G,I. Tumor - 1 each

J. Fallopian tube sections with tumor - 2

6: RIGHT ADNEXA

Labeled with the patient's name, designated "right adnexa", and received fresh in the Operating Room for the submission of tissue for research and subsequently fixed in formalin is a 7.0 x 7.0 x 3.0 cm markedly irregular, tan-brown, firm portion of tissue. The portion of fallopian tube measures up to 3.5 cm in length and averages up to 1.0 cm in external diameter. It is in close proximity of the tumor mass which measures up to 6.0 x 6.0 x 3.0 cm. The cut section of the fallopian tube grossly appears to be unremarkable. Tumor on cut sectioning is partially cystic and solid. There are areas of papillation also present in the solid

area. Focal areas of hemorrhages are also identified. The cyst range from 0.2 up to 3.0 cm. Most of the cyst has hemorrhagic material. Representative sections are submitted as follows.

(continued on next page)□

Page: 4

K. Fallopian tube - 2

L,M. Cyst with hemorrhagic material - 1 each

N-P. Tumor - 1 each

7: UTERUS AND CERVIX

Labeled with the patient's name, designated "uterus and cervix", and received in formalin is a 90 gram hysterectomy specimen with cervix. The uterus measures 7.0 cm from superior to inferior, 4.5 cm from cornu to cornu, and 2.6 cm from anterior to posterior surface. The ectocervix measures up to 2.5 cm x 2.5 cm and is mostly tan-white and smooth. The external os is pinpoint and measures up to 0.2 x 0.2 cm in the diameter. The serosal surface of the uterus is remarkable for two subserosal leiomyomas measuring up to 0.2 cm and 0.5 cm in the maximum diameter. They are present on the anterior surface. The left lateral wall of the cervix is remarkable for an area measuring up to 2.5 x 2.0 x 1.5 cm of adhesions. The posterior serosal has focal hemorrhages. The specimen is incised longitudinally. The endocervical canal measures up to 2.5 cm in length and measures up to 0.3 cm in the width. The endometrial cavity measures 3.2 x 1.2 cm. The endometrial thickness measures up to 0.1 cm. There are no grossly identifiable lesion. The

[page 4 of 5]
myometrium measures up to 1.5 cm in thickness. There is a 0.3 cm diameter nabothian cyst present in the ectocervical area. No other lesion is identified. Representative sections submitted as follows.

- Q,R. Left parametrium/area of hemorrhage and adhesion - 1 each
- S. Right parametrium - 1
- T. Anterior endocervix - 1
- U. Posterior endocervix - 1
- V. Anterior lower uterine segment - 1
- W. Posterior lower uterine segment - 1
- X. Anterior uterine body - 1
- Y. Posterior uterine body - 1
- Z. Two subserosal leiomyomas in the anterior uterine - 2

8: PELVIC TUMOR

Labeled with the patient's name, designated "pelvic tumor", and received in formalin are multiple, irregular, tan-brown portion of tissue aggregating up to 7.0 x 7.0 x 1.5 cm with the portion of tissue ranging from less than 1.0 cm up to 2.5 cm. Representative sections are submitted.

A1,B2. 1 each

9: RECTOSIGMOID TUMOR

Labeled with the patient's name, designated "rectosigmoid", and received in formalin are two irregular, firm, tan-brown portions of tissue measuring 0.6 x 0.6 x 0.4 cm and 1.3 x 1.0 x 0.6 cm. Entirely submitted.

C2. 2

10: APPENDIX

Labeled with the patient's name, designated "appendix", and received in formalin is a 2.5 cm long vermiform appendix measuring up to 0.5 cm in the external diameter. The attached fibroadipose tissue measures up to greatest diameter. The external surface is

(continued on next page)□

remarkable for a 0.5 x 0.4 cm firm nodularity. Representative sections are submitted.

page. 5

D2. Body, base, tip - 3

11: DIAPHRAGM TUMOR

Labeled with the patient's name, designated "diaphragm tumor", and received in formalin are three irregular, firm, tan-brown portion of tissue ranging from 0.3 cm up to 1.0 cm in greatest dimension. Entirely submitted.

E2. 3

12: GASTRO COLIC LIGAMENT NODULE

Labeled with the patient's name, designated "gastrocolic ligament nodule", and received in formalin is a 1.4 x 1.2 x 0.6 cm firm, tan-yellow portion of tissue. Entirely submitted.

F2. 1

13: LEFT PELVIC LYMPH NODE

Labeled with the patient's name, designated "left pelvic lymph node", and received in formalin is a 2.0 x 1.0 x 0.7 cm irregular, firm, tan portion of tissue. Entirely submitted.

G2. 1

[page 5 of 5]
14: LEFT OBTURATOR LYMPH NODE

Labeled with the patient's name, designated "left obturator lymph node", and received in formalin is a 3.0 x 2.5 x 1.0 cm irregular, firm, yellow-brown portion of tissue. The specimen is bisected and it is entirely submitted.

H2,I2. Bisected half of the same portion - 1 each

15: RIGHT OBTURATOR LYMPH NODE

Labeled with the patient's name, designated "right obturator lymph node", and received in formalin are three irregular, firm, yellow-brown portion of tissue ranging from 1.5 x 1.0 x 0.7 cm up to 2.0 x 1.2 x 1.0 cm. Entirely submitted as follows.

J2. Bigger portion of tissue bisected - 2

K2. Remaining two portions of tissue - 2

16: RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, designated "right pelvic lymph node", and received in formalin is a 1.7 x 1.0 x 0.5 cm irregular, yellow-brown portion of tissue. Entirely submitted.

L2. 1

17: RIGHT VAGINAL TUMOR

Labeled with the patient's name, designated "right vaginal tumor", and received in formalin are firm nodular areas measuring 1.0 cm and 1.5 cm. Representative sections.

M2,N2. 1 each

(continued on next page)□

Page: 6

Gross Stated by

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

FROZEN SECTION #1, SPECIMEN #5, LEFT TUBE AND OVARY:

- Adenocarcinoma
- Ovarian tumor mass 0.5 x 0.4 x 0.2 cm (from right ovary) and 0.4 x 0.3 x 0.3 cm (from left ovary) were taken for research

Special Studies: Frozen Section

SNOMED Code:

See Also:

Pathologist

I, _____, the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.
Date Finalled:

Source: NCI Genomic Data Commons file e717a1bf-fe38-47b2-adb3-70b62ee9ace0 (TCGA-23-1026.E41E1018-422B-4B4A-8732-C9389847830D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).